Somatic mutation profile of tumor specimen TCGA-97-8175-01A (aliquot TCGA-97-8175-01A-11D-2284-08) from TCGA case TCGA-97-8175, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Solid carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 55.3 years (20,206 days).
Specimen TCGA-97-8175-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e90dde05-c6b2-4e76-8eef-0e5ecc25bdbc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-97-8175-10A (Blood Derived Normal), aliquot TCGA-97-8175-10A-01D-2284-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aac15f05-c0d9-4ec5-9c0f-9f52ea9175cf

The open-access MAF lists 32 somatic variants for this specimen: 26 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 5, Nonsense Mutation 2, RNA 1, Frame Shift Del 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2313_2324dup p.Y772_A775dup | In Frame Ins (INS) | VAF 96/224 reads (43%) | hotspot (GDC flag); catalogued as rs397516975; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- SMARCA4 | c.3694G>A p.G1232S | Missense Mutation (SNP) | VAF 63/465 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV60785813, COSV60799159; called by muse, mutect2, varscan2
- TP53 | c.577C>A p.H193N | Missense Mutation (SNP) | VAF 26/90 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876658468, COSV52675896, COSV52688299, COSV52757395; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AASS | c.2518G>A p.D840N | Missense Mutation (SNP) | VAF 42/714 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV100741914; called by muse, mutect2
- ATP2A2 | c.751C>A p.Q251K | Missense Mutation (SNP) | VAF 24/396 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV100428991; called by muse, mutect2
- CDC6 | c.789G>A p.M263I | Missense Mutation (SNP) | VAF 109/220 reads (50%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV99266716; called by muse, mutect2, varscan2
- CUL7 | c.4589G>A p.G1530D | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV99539389; called by muse, mutect2, varscan2
- GCN1 | c.7049C>T p.T2350I | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.56); catalogued as COSV100326203; called by muse, mutect2, varscan2
- IGIP | c.101G>T p.C34F | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); catalogued as COSV60964063; called by muse, mutect2, varscan2
- KCNK16 | c.683A>G p.Y228C | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV64678539; called by muse, mutect2
- MAGEB6B | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 62/258 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs1456844558; called by muse, mutect2, varscan2
- MPO | c.442C>T p.Q148* | Nonsense Mutation (SNP) | VAF 11/69 reads (16%) | catalogued as COSV56565955, COSV99833102; called by muse, mutect2, varscan2
- NCAPH | c.1269G>A p.M423I | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.272); catalogued as COSV99546302; called by muse, mutect2, varscan2
- NUP214 | c.1517C>T p.S506F | Missense Mutation (SNP) | VAF 65/305 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV100845413; called by muse, mutect2, varscan2
- NUP37 | c.104T>C p.L35P | Missense Mutation (SNP) | VAF 48/289 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99195878; called by muse, mutect2, varscan2
- PEAR1 | c.3052C>T p.H1018Y | Missense Mutation (SNP) | VAF 33/215 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99442559; called by muse, mutect2, varscan2
- RGPD2 | c.4072A>T p.R1358* | Nonsense Mutation (SNP) | VAF 137/608 reads (23%) | catalogued as COSV100553180; called by muse, mutect2, varscan2
- SNTG1 | c.773C>A p.A258E | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as rs201460045, COSV52428603, COSV99386657; called by muse, mutect2
- SUDS3 | c.370G>T p.V124L | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as rs1174175836, COSV101288601; called by muse, mutect2, varscan2
- SVIL | c.1937G>T p.G646V | Missense Mutation (SNP) | VAF 34/195 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100881617; called by muse, mutect2, varscan2
- SYNJ2 | c.3190C>A p.Q1064K | Missense Mutation (SNP) | VAF 44/468 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.114); catalogued as COSV100840692; called by muse, mutect2
- SYVN1 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV99589310, COSV99589320; called by muse, mutect2, varscan2
- TNN | c.2027C>T p.T676I | Missense Mutation (SNP) | VAF 14/191 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV99513271; called by muse, mutect2
- ZNF461 | c.19A>C p.M7L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100831508; called by muse, mutect2, varscan2
- ZZEF1 | c.6183A>T p.E2061D | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV101068199; called by muse, mutect2, varscan2
- FLCN | c.29del p.F10Sfs*45 | Frame Shift Del (DEL) | VAF 20/71 reads (28%) | called by mutect2, pindel, varscan2
- INTS4 | c.1950A>G p.Q650= | Silent (SNP) | VAF 43/216 reads (20%) | catalogued as rs143324770; called by muse, mutect2, varscan2
- MPO | c.1419G>A p.R473= | Silent (SNP) | VAF 79/432 reads (18%) | catalogued as COSV99833099; called by muse, mutect2, varscan2
- NUP214 | c.1518C>G p.S506= | Silent (SNP) | VAF 58/300 reads (19%) | catalogued as COSV100845414; called by muse, mutect2, varscan2
- SPIDR | c.2469G>A p.V823= | Silent (SNP) | VAF 42/198 reads (21%) | catalogued as COSV99856291; called by muse, mutect2, varscan2
- VPS13B | c.3708C>A p.V1236= | Silent (SNP) | VAF 26/434 reads (6%) | catalogued as COSV100663930; called by muse, mutect2
- MIR1261 | n.49C>A | RNA (SNP) | VAF 19/119 reads (16%) | catalogued as rs1307677612; called by muse, mutect2, varscan2
